TCGA case TCGA-DX-A8BN — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/47f18eee-3e56-4388-aac3-9ac141bcb414

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 78.7 years (28,760 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 10.9; Tumor width measurement: 6.1.

Follow-up (2 entries)
- Days to follow up: 845 days (2.3 years); Disease response: Tumor Free.
- Days to follow up: 1,161 days (3.2 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A8BN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 530 mg.
  Slide TCGA-DX-A8BN-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A8BN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A8BN-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 560 mg.
  Slide TCGA-DX-A8BN-11A-02-TSB: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 4.0.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Radiation treatment: Days from index date to radiation therapy started: 58; Days from index date to radiation therapy ended: 107; Radiation therapy type: External; Radiation total dose: 6300; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 35; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,161 days; disease-specific survival: no event (censored), 1,161 days; progression-free interval: no event (censored), 1,161 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A8BN-01A-11D-A37B-01): tumor purity 0.6, ploidy 3.83, whole-genome doublings 1.
